Somatic mutation profile of tumor specimen TCGA-14-0813-01A (aliquot TCGA-14-0813-01A-01D-1492-08) from TCGA case TCGA-14-0813, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.3 years (28,582 days).
Specimen TCGA-14-0813-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7436f4d4-eeca-4c93-967a-868dcabe77ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0813-10A (Blood Derived Normal), aliquot TCGA-14-0813-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/146b341d-06f3-41b4-90c5-aece9556c240

The open-access MAF lists 103 somatic variants for this specimen: 73 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 26, Frame Shift Del 3, Splice Site 3, Intron 2, 3'Flank 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs786204931, CM020755, COSV64290794, COSV64294365; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 32/89 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1694C>A p.T565N (on ENST00000373993 / NM_138932.2; = p.T557N on NM_014576.4) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.04); catalogued as rs1437937139, COSV51044379; called by muse, mutect2
- ABHD17B | c.566T>C p.I189T | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs1393564101, COSV61007235; called by muse, mutect2, varscan2
- ACVRL1 | c.1364T>G p.L455R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66359744; called by muse, mutect2, varscan2
- AHNAK | c.16264G>A p.V5422I | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as rs763304834, COSV57204985; called by muse, mutect2, varscan2
- AK9 | c.326del p.H109Pfs*17 | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | catalogued as COSV53420226; called by mutect2, pindel, varscan2
- ARHGAP4 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 84/135 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1569546003, COSV100604122, COSV63130805; called by muse, mutect2, varscan2
- AVPR1B | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782061896, COSV65637835; called by muse, mutect2, varscan2
- CACNG2 | c.295+1G>A p.X99_splice | Splice Site (SNP) | VAF 66/196 reads (34%) | catalogued as COSV55632987; called by muse, mutect2, varscan2
- CD55 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 132/272 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58576674; called by muse, mutect2, varscan2
- CHD2 | c.5026G>A p.G1676R | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV67707284; called by muse, mutect2, varscan2
- CHL1 | c.1932G>T p.E644D (on ENST00000397491 / NM_001253387.1; = p.E660D on NM_006614.4) | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV56588544; called by muse, mutect2, varscan2
- COL4A5 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.27); catalogued as COSV100086756, COSV60373166; called by muse, mutect2
- CRYBG1 | c.3571C>T p.R1191C | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs574757027, COSV64811095; called by muse, mutect2, varscan2
- DHH | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57203063; called by muse, mutect2, varscan2
- DRD5 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs754629025, COSV100431959, COSV58577042, COSV58577153; called by muse, mutect2, varscan2
- EFCAB12 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV58176426; called by muse, mutect2, varscan2
- FARSA | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV58904500; called by muse, mutect2, varscan2
- FBN1 | c.5433G>T p.E1811D | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57311600; called by muse, mutect2, varscan2
- GORAB | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs368371528, COSV100883760; called by muse, mutect2, varscan2
- HK3 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs781200940, COSV52837709; called by muse, mutect2, varscan2
- HOXA9 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as rs1000950303, COSV58655859; called by muse, mutect2, varscan2
- IGF2BP1 | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51729832; called by muse, mutect2, varscan2
- IL18R1 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV52123029, COSV52125472; called by muse, mutect2, varscan2
- IL4R | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs370524692; called by muse, mutect2, varscan2
- KLF17 | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV64856018; called by muse, mutect2, varscan2
- LAMB4 | c.2749C>T p.P917S | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52732213; called by muse, mutect2
- LMBRD1 | c.1111A>T p.S371C (on ENST00000649011; = p.S349C on NM_018368.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV65296418; called by muse, mutect2, varscan2
- LRRC7 | c.1791A>T p.R597S (on ENST00000651989 / NM_001370785.2; = p.R564S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV50420946; called by muse, mutect2, varscan2
- MAGEA12 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 105/143 reads (73%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV63294327; called by muse, mutect2, varscan2
- MET | c.2198C>A p.T733K | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV59258191; called by muse, mutect2, varscan2
- MKRN3 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 56/139 reads (40%) | catalogued as COSV58809134; called by muse, mutect2, varscan2
- MLIP | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV51438151; called by muse, mutect2
- MS4A14 | c.1447T>A p.S483T | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.026); catalogued as COSV55732751; called by muse, mutect2
- MSR1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs748304603, COSV50506732, COSV50507717; called by muse, mutect2, varscan2
- MUSK | c.129A>T p.E43D | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV51898104; called by muse, mutect2
- NBAS | c.5206C>A p.P1736T | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55715095; called by muse, mutect2, varscan2
- NEGR1 | c.279T>G p.I93M | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV60833856; called by muse, mutect2, varscan2
- NFIB | c.617-2A>T p.X206_splice | Splice Site (SNP) | VAF 24/34 reads (71%) | catalogued as COSV66625776; called by muse, mutect2, varscan2
- NINL | c.2882C>T p.P961L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV53999629; called by muse, mutect2
- NLRP7 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.668); catalogued as rs778545569, CM1210279, COSV60172027; called by muse, mutect2, varscan2
- OCIAD1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs150423557; called by muse, mutect2
- OR2L13 | c.204G>T p.M68I | Missense Mutation (SNP) | VAF 118/391 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.079); catalogued as COSV63549564; called by muse, mutect2, varscan2
- OR2T4 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 97/376 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs370187385, COSV63543913; called by muse, mutect2, varscan2
- OR56B4 | c.44T>A p.I15N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100337685, COSV57204157; called by muse, mutect2, varscan2
- OR5AR1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 130/352 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs143043362; called by muse, mutect2, varscan2
- PCDHB5 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV50648059; called by muse, varscan2
- PCGF6 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs200230704, COSV61494486; called by muse, mutect2, varscan2
- PLCG2 | c.2261A>C p.D754A | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV63867920; called by muse, mutect2, varscan2
- POLQ | c.4856A>C p.K1619T | Missense Mutation (SNP) | VAF 201/515 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV51747635; called by muse, mutect2, varscan2
- PPP1R16B | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV55375092; called by muse, mutect2, varscan2
- PRKD1 | c.2074G>A p.V692M | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.464); catalogued as rs758594741, COSV59559687, COSV99045699; called by muse, mutect2
- PRX | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs759512054, COSV52528220; called by muse, mutect2, varscan2
- PSMA8 | c.495+2T>A p.X165_splice | Splice Site (SNP) | VAF 103/283 reads (36%) | catalogued as COSV57601460; called by muse, mutect2, varscan2
- PTCHD4 | c.2420T>C p.L807P | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59798578; called by muse, mutect2, varscan2
- RFX6 | c.526del p.L176Sfs*2 | Frame Shift Del (DEL) | VAF 27/97 reads (28%) | catalogued as COSV60589502; called by mutect2, pindel, varscan2
- SCN7A | c.4073G>A p.R1358H | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs766963704, COSV69269732; called by muse, mutect2, varscan2
- SCRIB | c.2389G>A p.V797M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782729497; called by muse, mutect2, varscan2
- SERPINB3 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as rs143634391; called by muse, mutect2, varscan2
- SIGLEC8 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs200891335, COSV100367463; called by muse, varscan2
- SIM1 | c.1616C>G p.P539R | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV53489766, COSV53495553; called by muse, mutect2, varscan2
- SIMC1 | c.614G>A p.R205Q (on ENST00000443967 / NM_001308196.1; = p.R224Q on NM_001308195.2) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs371703466; called by muse, mutect2, varscan2
- SIRPB1 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54377444; called by muse, mutect2
- TLN2 | c.5135G>A p.G1712E | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.354); catalogued as rs1345275868, COSV60886945; called by muse, mutect2, varscan2
- TULP1 | c.29A>G p.E10G | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57694027; called by muse, mutect2
- USP29 | c.1711T>A p.S571T | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as COSV54140769; called by muse, mutect2, varscan2
- VPS13C | c.1342G>T p.A448S (on ENST00000644861 / NM_020821.3; = p.A405S on NM_017684.5) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51427487; called by muse, mutect2, varscan2
- ZNF362 | c.531G>C p.K177N | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.307); catalogued as COSV65031170; called by muse, mutect2, varscan2
- ZNF395 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60428003; called by muse, mutect2, varscan2
- ZNF569 | c.397A>G p.R133G | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57594078; called by muse, mutect2, varscan2
- ZNF681 | c.1123T>G p.F375V | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68073749; called by muse, varscan2
- KPNB1 | c.407del p.N136Mfs*11 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- ACVRL1 | c.1365G>T p.L455= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV101188156, COSV66359749; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2982C>G p.T994= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs776052560, COSV65889730; called by muse, mutect2, varscan2
- AFF2 | c.735C>T p.A245= | Silent (SNP) | VAF 36/251 reads (14%) | catalogued as rs782663982, COSV100649822, COSV60682910; called by muse, mutect2, varscan2
- ALPG | c.1266C>T p.D422= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1339270909, COSV54965308; called by muse, mutect2, varscan2
- ASXL2 | c.3288G>A p.Q1096= | Silent (SNP) | VAF 61/211 reads (29%) | catalogued as COSV55468736; called by muse, mutect2, varscan2
- BMP7 | c.754C>T p.L252= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV101215578, COSV67779870; called by muse, mutect2, varscan2
- CDRT1 | c.810G>A p.G270= | Silent (SNP) | VAF 83/203 reads (41%) | catalogued as rs779865994, COSV55410894; called by muse, mutect2, varscan2
- DSP | c.7674T>A p.A2558= | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as COSV65796492; called by muse, mutect2
- EGF | c.1038C>A p.A346= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as COSV54476707; called by muse, mutect2, varscan2
- FOXD4L6 | c.1044G>A p.P348= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs1310445416; called by mutect2, varscan2
- GDF2 | c.912G>A p.T304= | Silent (SNP) | VAF 37/60 reads (62%) | catalogued as rs201627211; called by muse, mutect2, varscan2
- ITGA6 | c.1080G>A p.A360= (on ENST00000442250; = p.A321= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs745506887, COSV51220453, COSV99905757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MASP2 | c.165C>T p.Y55= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1460922742, COSV68897675; called by muse, mutect2, varscan2
- MOB1B | c.618A>G p.E206= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs553172790, COSV58673199; called by muse, mutect2, varscan2
- OR10Z1 | c.88T>C p.L30= | Silent (SNP) | VAF 12/268 reads (4%) | catalogued as COSV63526680; called by muse, mutect2
- OR6B2 | c.132C>A p.A44= | Silent (SNP) | VAF 59/285 reads (21%) | catalogued as COSV53153048; called by muse, mutect2, varscan2
- PCDH7 | c.1152G>T p.T384= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV62337336, COSV62341827; called by muse, mutect2, varscan2
- QSER1 | c.1095G>A p.K365= (on ENST00000399302; = p.K494= on NM_001076786.3) | Silent (SNP) | VAF 17/271 reads (6%) | catalogued as rs758611478, COSV67901920; called by muse, mutect2
- RBBP8 | c.1659C>G p.P553= | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as COSV59091207, COSV59091427; called by muse, mutect2
- SH3GL3 | c.540C>T p.D180= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs138675150; called by muse, mutect2, varscan2
- SIPA1L2 | c.3195G>A p.T1065= | Silent (SNP) | VAF 127/242 reads (52%) | catalogued as rs372853782; called by muse, mutect2, varscan2
- SLC39A8 | c.1347C>T p.L449= | Silent (SNP) | VAF 38/170 reads (22%) | catalogued as rs1464550838, COSV63222159; called by muse, mutect2, varscan2
- SLF2 | c.729C>T p.Y243= | Silent (SNP) | VAF 39/71 reads (55%) | catalogued as COSV53271548; called by muse, mutect2, varscan2
- TBC1D9 | c.2223G>A p.V741= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as COSV71307049; called by muse, mutect2, varscan2
- TCTE1 | c.165G>A p.R55= | Silent (SNP) | VAF 47/135 reads (35%) | catalogued as COSV65255209; called by muse, mutect2, varscan2
- TPCN1 | c.2193G>C p.R731= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV59233283; called by muse, mutect2, varscan2
- ASPG | chr14:104117503 C>T | 3'Flank (SNP) | VAF 16/30 reads (53%) | catalogued as rs1345581826; called by muse, mutect2
- KRT18P23 | chr22:44571465 C>T | 3'Flank (SNP) | VAF 11/36 reads (31%) | catalogued as rs764813917; called by muse, mutect2, varscan2
- OBSCN | c.11659+4373C>T | Intron (SNP) | VAF 47/194 reads (24%) | catalogued as rs773990433, COSV52758485; called by muse, mutect2, varscan2
- TTN | c.34265-5248A>C | Intron (SNP) | VAF 14/126 reads (11%) | catalogued as COSV60039271, COSV60380796; called by muse, mutect2
